Somatic mutation profile of tumor specimen TCGA-EB-A44O-01A (aliquot TCGA-EB-A44O-01A-11D-A25O-08) from TCGA case TCGA-EB-A44O, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 69.9 years (25,537 days).
Specimen TCGA-EB-A44O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b56113a-a6bf-4625-8bf7-e8d2efbaec14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A44O-10A (Blood Derived Normal), aliquot TCGA-EB-A44O-10A-01D-A25O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c5a98ac6-8a62-4550-af4b-b429f249bb60

The open-access MAF lists 607 somatic variants for this specimen: 391 protein-altering or splice-affecting, 197 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 356, Silent 197, Nonsense Mutation 27, Intron 8, RNA 5, 3'UTR 3, Splice Site 2, Frame Shift Del 2, Splice Region 2, 3'Flank 2, 5'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEP63 | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 29/72 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777174766, COSV59674760; called by muse, mutect2, varscan2
- NCR1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 40/54 reads (74%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as COSV52555848; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 52/77 reads (68%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- RAC1 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 15/55 reads (27%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as rs1057519874, COSV61821563, COSV61823187; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- TYR | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs796051880, CM156816, COSV54472937; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.999A>T p.Q333H | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV50962606, COSV50984412; called by muse, mutect2, varscan2
- ABCA12 | c.7118T>A p.L2373H (on ENST00000272895 / NM_173076.3; = p.L2055H on NM_015657.3) | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55956388; called by muse, mutect2, varscan2
- ABCA2 | c.2593C>T p.R865* (on ENST00000614293; = p.R835* on NM_001606.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 25/58 reads (43%) | catalogued as rs746447171, COSV99687631; called by muse, mutect2, varscan2
- ABCD1 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM106585, COSV99497568; called by muse, mutect2
- ABCD1 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM960035, COSV99497570; called by muse, mutect2
- ABCF3 | c.1567G>A p.V523M | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV53052105, COSV99491224; called by muse, mutect2, varscan2
- ABCG4 | c.1111C>T p.L371F | Missense Mutation (SNP) | VAF 151/224 reads (67%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV56643310; called by muse, mutect2, varscan2
- ACE | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.116); catalogued as COSV52005854; called by muse, mutect2, varscan2
- ACSM2B | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV61656653; called by muse, mutect2, varscan2
- ACSM3 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV55501095; called by muse, mutect2, varscan2
- ADAM29 | c.1640C>T p.S547L | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.449); catalogued as rs1301611574, COSV100822198, COSV63662573; called by muse, mutect2, varscan2
- ADAM7 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV51535893; called by muse, varscan2
- ADAMDEC1 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.034); catalogued as rs1354350441, COSV56475007; called by muse, mutect2, varscan2
- ADAMTS20 | c.1501C>T p.P501S | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780705641, COSV67130318; called by muse, mutect2, varscan2
- ADD2 | c.1642G>A p.D548N | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.011); catalogued as COSV52459669; called by muse, mutect2, varscan2
- ADGRB2 | c.4727C>T p.P1576L (on ENST00000373658 / NM_001364857.2; = p.P1575L on NM_001294335.2) | Missense Mutation (SNP) | VAF 26/32 reads (81%) | SIFT tolerated (0.17); PolyPhen benign (0.041); catalogued as COSV57072852; called by muse, mutect2, varscan2
- AFM | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.879); catalogued as COSV56919820; called by muse, mutect2, varscan2
- AIP | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 38/52 reads (73%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs762219351, COSV54160411; called by muse, mutect2, varscan2
- AIRE | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as rs768840365, COSV52393715; called by muse, mutect2, varscan2
- AKNA | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as rs758582964, COSV56312302; called by muse, mutect2, varscan2
- AL031777.2 | c.485G>A p.R162K | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated, low confidence (0.31); catalogued as rs1280076170, COSV61911833; called by muse, mutect2, varscan2
- ALMS1 | c.3394C>T p.Q1132* | Nonsense Mutation (SNP) | VAF 55/148 reads (37%) | catalogued as COSV100042486, COSV52516065; called by muse, mutect2, varscan2
- ALOX5 | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.793); catalogued as COSV65551723; called by muse, mutect2, varscan2
- ANAPC2 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.424); catalogued as rs755366409, COSV58807175; called by muse, mutect2, varscan2
- ANKRD30A | c.2857G>A p.G953R (on ENST00000611781; = p.G897R on NM_052997.2) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.609); catalogued as COSV64608716; called by muse, mutect2, varscan2
- AP2A2 | c.1822G>T p.E608* | Nonsense Mutation (SNP) | VAF 27/79 reads (34%) | catalogued as COSV59959859, COSV59964008; called by muse, mutect2, varscan2
- APBB2 | c.571C>T p.Q191* | Nonsense Mutation (SNP) | VAF 77/209 reads (37%) | catalogued as COSV55951286; called by muse, mutect2, varscan2
- APOB | c.12731C>T p.S4244F | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV51921429; called by muse, mutect2, varscan2
- APOB | c.5947C>T p.L1983F | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.033); catalogued as COSV51932559; called by muse, mutect2, varscan2
- APOB | c.3821C>T p.P1274L | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1204565963, COSV51932571; called by muse, mutect2, varscan2
- ARHGAP6 | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 26/37 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV57294814; called by muse, mutect2, varscan2
- ARMC4 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as COSV53464457; called by muse, mutect2, varscan2
- ARMC5 | c.2321T>G p.F774C | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51655895; called by muse, mutect2, varscan2
- ASS1 | c.1022C>T p.S341F | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM091440, COSV61689065; called by muse, mutect2, varscan2
- ATF7IP | c.3407C>T p.P1136L | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV53769698; called by muse, mutect2, varscan2
- ATP6V0A4 | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.816); catalogued as COSV59474806; called by muse, mutect2, varscan2
- BAIAP3 | c.1370T>G p.L457R | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as rs776783816, COSV60979521; called by muse, mutect2
- BAIAP3 | c.2083C>T p.P695S | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT tolerated (0.81); PolyPhen benign (0.24); catalogued as rs1271529246, COSV50103501, COSV50105838; called by muse, mutect2, varscan2
- BAIAP3 | c.2084C>T p.P695L | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as rs763302658, COSV99136215; called by muse, mutect2, varscan2
- BANK1 | c.451C>T p.Q151* | Nonsense Mutation (SNP) | VAF 28/62 reads (45%) | catalogued as COSV59841750; called by muse, mutect2, varscan2
- BBS9 | c.932T>C p.M311T | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV54165213; called by muse, mutect2, varscan2
- BEST2 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs1233783533, COSV50363175; called by muse, mutect2, varscan2
- BIRC6 | c.12863A>T p.Y4288F | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as COSV70198364; called by muse, mutect2, varscan2
- BMI1 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV64958962; called by muse, mutect2, varscan2
- BRD4 | c.33G>T p.L11F | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54585266; called by muse, mutect2, varscan2
- BRD7 | c.1400T>G p.L467* | Nonsense Mutation (SNP) | VAF 14/22 reads (64%) | catalogued as COSV67158630; called by muse, mutect2, varscan2
- BSN | c.4453C>T p.P1485S | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56516488; called by muse, mutect2, varscan2
- BTBD11 | c.1678G>A p.D560N (on ENST00000280758 / NM_001018072.2; = p.D97N on NM_001017523.2) | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99775771; called by muse, mutect2, varscan2
- BTNL8 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 66/93 reads (71%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs753356741, COSV51458261; called by muse, mutect2, varscan2
- C11orf65 | c.124A>G p.R42G | Missense Mutation (SNP) | VAF 35/45 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV67597327; called by muse, mutect2, varscan2
- C2CD2 | c.1646C>T p.S549F | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as COSV61599262; called by muse, mutect2, varscan2
- C3orf56 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs376315163; called by muse, mutect2, varscan2
- C6 | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54708778; called by muse, mutect2, varscan2
- C6orf201 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.091); catalogued as COSV60986087; called by muse, mutect2, varscan2
- CACNA1A | c.1628C>T p.T543M | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as rs753564161, COSV64196090; called by muse, mutect2, varscan2
- CACNA1B | c.6727C>T p.P2243S | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.026); catalogued as COSV53122940; called by muse, mutect2, varscan2
- CARD14 | c.892C>T p.R298* | Nonsense Mutation (SNP) | VAF 14/46 reads (30%) | catalogued as rs772958714, COSV60123003; called by muse, mutect2, varscan2
- CCBE1 | c.1142T>A p.M381K | Missense Mutation (SNP) | VAF 66/163 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV67949725; called by muse, mutect2, varscan2
- CCDC105 | c.134C>T p.T45I | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV52963756; called by muse, mutect2, varscan2
- CCDC113 | c.796A>G p.K266E | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (0.96); PolyPhen benign (0.096); catalogued as rs1202965039, COSV54685744; called by muse, mutect2, varscan2
- CCDC136 | c.1075C>T p.H359Y | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV99922639; called by muse, mutect2, varscan2
- CCDC30 | c.2320G>A p.E774K (on ENST00000340612; = p.E731K on NM_001080850.3) | Missense Mutation (SNP) | VAF 33/42 reads (79%) | SIFT tolerated (0.32); PolyPhen benign (0.042); catalogued as COSV59245951; called by muse, mutect2, varscan2
- CCNB3 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT tolerated (0.5); PolyPhen benign (0.078); catalogued as COSV52072501; called by muse, mutect2, varscan2
- CD2AP | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0.013); catalogued as COSV63760399; called by muse, mutect2, varscan2
- CD58 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated (0.06); PolyPhen benign (0.157); catalogued as rs764273333, COSV59841507, COSV59841764; called by muse, mutect2, varscan2
- CDH18 | c.1633A>G p.N545D | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as rs776496064, COSV56916525; called by muse, mutect2, varscan2
- CDK7 | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56513081; called by muse, mutect2, varscan2
- CEACAM21 | c.749T>C p.L250P (on ENST00000401445 / NM_001098506.4; = p.L249P on NM_033543.6) | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV51813841; called by muse, mutect2, varscan2
- CEMIP | c.1576G>A p.G526S | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54991398; called by muse, mutect2, varscan2
- CER1 | c.582T>G p.H194Q | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as COSV66603130; called by muse, mutect2, varscan2
- CFHR5 | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 54/69 reads (78%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as rs868847668, COSV56820969; called by muse, mutect2, varscan2
- CHAT | c.1694G>A p.G565E | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868240139, COSV60323821; called by muse, mutect2, varscan2
- CHD6 | c.7261C>T p.P2421S | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1465644381, COSV64690012; called by muse, mutect2, varscan2
- CLCN4 | c.1985G>A p.R662K | Missense Mutation (SNP) | VAF 42/52 reads (81%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV66466218; called by muse, mutect2, varscan2
- CLEC4M | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 119/136 reads (88%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs138729831; called by muse, mutect2, varscan2
- CNBD1 | c.1261A>T p.K421* | Nonsense Mutation (SNP) | VAF 18/29 reads (62%) | catalogued as COSV73073142; called by muse, mutect2, varscan2
- CNGB3 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60688526; called by muse, mutect2, varscan2
- CNTNAP1 | c.246C>G p.I82M | Missense Mutation (SNP) | VAF 54/99 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99226406; called by muse, mutect2, varscan2
- CNTNAP1 | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 54/99 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs1398891828, COSV99226408; called by muse, mutect2, varscan2
- COL4A3 | c.3266G>A p.G1089D | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM143823, COSV59257864; called by muse, mutect2, varscan2
- COL5A3 | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs759526885, COSV53409582; called by muse, mutect2, varscan2
- COLEC11 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.155); catalogued as COSV52592624; called by muse, mutect2, varscan2
- CPT1C | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 30/32 reads (94%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs759904221, COSV54918786, COSV54920289, COSV99773338; called by muse, mutect2, varscan2
- CSMD2 | c.6102G>A p.M2034I | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs375268880, COSV53904369; called by muse, mutect2, varscan2
- CSMD2 | c.3871C>T p.P1291S | Missense Mutation (SNP) | VAF 116/139 reads (83%) | SIFT deleterious (0.05); PolyPhen benign (0.258); catalogued as rs1305465700, COSV53904397; called by muse, mutect2, varscan2
- CSMD3 | c.1520C>T p.T507I (on ENST00000297405 / NM_001363185.1; = p.T403I on NM_052900.3) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.2); catalogued as COSV52159060, COSV99828275; called by muse, mutect2, varscan2
- CSPP1 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs768054883, COSV51583502; called by muse, mutect2, varscan2
- CUX2 | c.3718C>T p.P1240S | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as rs772003882, COSV55629926; called by muse, mutect2, varscan2
- CYP2C9 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 94/137 reads (69%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.932); catalogued as rs150891702, COSV53247038; called by muse, mutect2, varscan2
- DGKI | c.2167C>T p.R723C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs760167594, COSV55937658; called by muse, mutect2, varscan2
- DHDDS | c.989C>A p.T330N (on ENST00000236342 / NM_001319959.1; = p.T331N on NM_024887.3) | Missense Mutation (SNP) | VAF 57/68 reads (84%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.007); catalogued as rs769003252, COSV52576344; called by muse, mutect2, varscan2
- DNAH11 | c.6643G>A p.G2215S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60952528; called by muse, mutect2, varscan2
- DNAH17 | c.3888G>A p.W1296* | Nonsense Mutation (SNP) | VAF 20/53 reads (38%) | catalogued as COSV67752716; called by muse, mutect2, varscan2
- DNAH3 | c.2941G>A p.E981K | Missense Mutation (SNP) | VAF 95/200 reads (48%) | SIFT tolerated (0.53); PolyPhen benign (0.162); catalogued as COSV54514311; called by muse, mutect2, varscan2
- DNAH3 | c.401C>T p.T134I | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV54509247, COSV54516917; called by muse, mutect2, varscan2
- DNAH7 | c.8719G>A p.D2907N | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.4); catalogued as COSV56760925; called by muse, mutect2, varscan2
- DNAH9 | c.8132C>T p.S2711L | Missense Mutation (SNP) | VAF 36/43 reads (84%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV52345909; called by muse, mutect2, varscan2
- DOK6 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0.023); catalogued as COSV66926338; called by muse, mutect2, varscan2
- DPF3 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.973); catalogued as COSV63499893; called by muse, mutect2, varscan2
- DSG1 | c.1805C>T p.P602L | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as rs867858598, COSV57134752; called by muse, mutect2, varscan2
- DUOX1 | c.3782G>A p.G1261E | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.04); catalogued as COSV58479715; called by muse, mutect2, varscan2
- EBF2 | c.1220G>A p.R407K | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV68776992; called by muse, mutect2, varscan2
- ELFN2 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV68744064; called by muse, mutect2, varscan2
- ENPP6 | c.1221G>A p.W407* | Nonsense Mutation (SNP) | VAF 30/92 reads (33%) | catalogued as COSV57067473; called by muse, mutect2, varscan2
- ENTPD6 | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); catalogued as COSV61751385; called by muse, mutect2, varscan2
- EPHA8 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 85/112 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs142067038; called by muse, mutect2, varscan2
- ERICH3 | c.3971G>A p.G1324E | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs935786581, COSV58604873; called by muse, mutect2, varscan2
- EWSR1 | c.745C>T p.Q249* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as rs1403104724, COSV58423098; called by muse, mutect2, varscan2
- FAM135B | c.1819T>A p.S607T | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV52719699; called by muse, mutect2
- FAM135B | c.1817C>T p.S606F | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV52719715, COSV99417311; called by muse, mutect2
- FAM170A | c.829C>T p.Q277* | Nonsense Mutation (SNP) | VAF 45/66 reads (68%) | catalogued as COSV58924844, COSV58925046; called by muse, mutect2, varscan2
- FAM171B | c.2104G>A p.D702N | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100488973, COSV59002675; called by muse, mutect2, varscan2
- FAM241B | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 44/53 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1325127477, COSV64768007; called by muse, mutect2, varscan2
- FAM83D | c.577C>T p.L193F | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267605929, COSV54157211; called by muse, mutect2
- FAM90A1 | c.569G>C p.S190T | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.725); catalogued as COSV56711674; called by muse, mutect2, varscan2
- FBN1 | c.5050G>A p.G1684R | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1555396841, COSV57314783; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBXO43 | c.1536G>A p.M512I | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV71053776; called by muse, mutect2, varscan2
- FBXW10 | c.1487G>A p.G496E | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57316543; called by muse, mutect2, varscan2
- FCHO1 | c.2185C>T p.P729S | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99406105; called by muse, mutect2
- FCHO1 | c.2186C>T p.P729L | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99406106; called by muse, mutect2
- FCRL5 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as COSV62513595, COSV62519727; called by muse, mutect2, varscan2
- FGD5 | c.3265G>A p.E1089K | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1345146757, COSV53241360; called by muse, mutect2, varscan2
- FHDC1 | c.2831C>T p.S944F | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52599255; called by muse, mutect2, varscan2
- FLNB | c.4466G>A p.G1489E | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs1230330528, COSV55877320; called by muse, mutect2, varscan2
- FRAS1 | c.5654A>G p.N1885S | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV53605122; called by muse, mutect2
- FRAS1 | c.7459C>T p.P2487S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV53605153; called by muse, mutect2, varscan2
- FRAS1 | c.9466G>A p.E3156K | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs1227013948, COSV53605175; called by muse, mutect2, varscan2
- FRMPD1 | c.2513G>T p.R838I | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66699965; called by muse, mutect2, varscan2
- FUT6 | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 48/71 reads (68%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs375242162; called by muse, mutect2, varscan2
- FZD3 | c.497C>A p.P166H | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53535220; called by muse, mutect2, varscan2
- GALNT12 | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772804071, COSV66662565; called by muse, mutect2
- GDNF | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58479130; called by muse, mutect2, varscan2
- GNPTAB | c.2678C>T p.P893L | Missense Mutation (SNP) | VAF 70/158 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746870755, COSV54779110; called by muse, mutect2, varscan2
- GPC2 | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as rs369003293, COSV99444711; called by muse, mutect2, varscan2
- GRAP2 | c.22G>A p.D8N | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1180492684, COSV59994854; called by muse, mutect2, varscan2
- GSDMC | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52694901; called by muse, mutect2, varscan2
- H2AC1 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.02); catalogued as COSV51237141; called by muse, mutect2, varscan2
- HAL | c.1406G>A p.R469K | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV54117483; called by muse, mutect2, varscan2
- HCRTR2 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 76/184 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100904231, COSV63795269; called by muse, mutect2, varscan2
- HGS | c.14G>T p.S5I | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV61267550; called by muse, mutect2
- HIVEP2 | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 56/91 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV50009358; called by muse, mutect2, varscan2
- HK3 | c.289G>T p.G97W | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99458532; called by muse, mutect2, varscan2
- HNRNPUL1 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 96/118 reads (81%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as COSV54561787; called by muse, mutect2, varscan2
- HRNR | c.5894G>A p.G1965D | Missense Mutation (SNP) | VAF 120/1199 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.822); catalogued as COSV64257069, COSV64258851; called by muse, mutect2, varscan2
- HS3ST1 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0.085); catalogued as COSV50023411; called by muse, mutect2, varscan2
- HSPB3 | c.335G>A p.R112K | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57356836; called by muse, mutect2, varscan2
- IDE | c.2610G>T p.M870I | Missense Mutation (SNP) | VAF 53/86 reads (62%) | SIFT tolerated (0.17); PolyPhen benign (0.183); catalogued as COSV56422826; called by muse, mutect2, varscan2
- IFNA6 | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 89/129 reads (69%) | SIFT tolerated (0.13); PolyPhen benign (0.18); catalogued as rs137921767; called by muse, mutect2, varscan2
- IFT27 | c.493C>T p.H165Y (on ENST00000433985 / NM_001363003.2; = p.H164Y on NM_006860.5) | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100503548; called by muse, mutect2, varscan2
- IFT27 | c.492C>A p.F164L (on ENST00000433985 / NM_001363003.2; = p.F163L on NM_006860.5) | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.822); catalogued as COSV100503549, COSV61416701; called by muse, mutect2, varscan2
- IGFN1 | c.2498C>T p.S833L (on ENST00000295591 / NM_001367841.1; = p.S3290L on NM_001164586.2) | Missense Mutation (SNP) | VAF 28/34 reads (82%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs377537016; called by muse, mutect2, varscan2
- IGSF1 | c.914G>A p.G305D | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.999); catalogued as COSV63837084; called by muse, mutect2, varscan2
- IKZF1 | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58784777; called by muse, mutect2, varscan2
- IL18RAP | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.033); catalogued as COSV51825441; called by muse, mutect2, varscan2
- IL1R1 | c.1628G>A p.R543Q | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.024); catalogued as rs749524190, COSV52105792; called by muse, mutect2, varscan2
- IL2RB | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV53425402; called by muse, mutect2, varscan2
- INPP5K | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV100233745, COSV100233872; called by muse, mutect2, varscan2
- INPP5K | c.1066C>A p.P356T | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV100233746; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1480G>A p.D494N (on ENST00000485419 / NM_001197113.1; = p.D418N on NM_014575.3) | Missense Mutation (SNP) | VAF 36/63 reads (57%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs770497985, COSV61843063; called by muse, mutect2, varscan2
- IQGAP2 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.86); PolyPhen benign (0.017); catalogued as COSV57167677, COSV57172210; called by muse, mutect2, varscan2
- IRAG2 | c.4042G>A p.E1348K (on ENST00000636465; = p.E393K on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as COSV57231647; called by muse, mutect2, varscan2
- ITGA4 | c.1225G>A p.G409R | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51999052; called by muse, mutect2, varscan2
- JCAD | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 77/206 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs772929418, COSV64757781; called by muse, mutect2, varscan2
- KCNJ6 | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as rs1346897755, COSV55712859; called by muse, mutect2
- KCNU1 | c.2578C>T p.P860S | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as COSV67755028; called by muse, mutect2, varscan2
- KHDRBS3 | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV63417232; called by muse, mutect2, varscan2
- KIAA0100 | c.2414C>T p.P805L | Missense Mutation (SNP) | VAF 38/56 reads (68%) | SIFT tolerated (0.33); PolyPhen benign (0.018); catalogued as COSV66492088; called by muse, mutect2, varscan2
- KIAA1109 | c.8840C>T p.S2947F | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV52669821, COSV99175602; called by muse, mutect2, varscan2
- KIF4B | c.3439C>T p.P1147S | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0.05); PolyPhen benign (0.156); catalogued as COSV70528972; called by muse, mutect2, varscan2
- KIRREL1 | c.1822G>T p.V608L | Missense Mutation (SNP) | VAF 55/69 reads (80%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as COSV63286585; called by muse, mutect2, varscan2
- KLHL40 | c.1306G>A p.D436N | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as rs372145157; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KMT2D | c.14237G>A p.R4746Q | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.683); catalogued as rs1431836046, COSV56431206; called by muse, mutect2, varscan2
- KNL1 | c.2593C>T p.P865S (on ENST00000346991 / NM_170589.5; = p.P839S on NM_144508.5) | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV61153758; called by muse, mutect2, varscan2
- KRT72 | c.1175T>G p.L392R | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1184888306, COSV53373958; called by muse, mutect2, varscan2
- LAMP3 | c.1112G>A p.G371E | Missense Mutation (SNP) | VAF 64/138 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV55614490; called by muse, mutect2, varscan2
- LDLR | c.2303C>T p.S768F | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV52942821; called by muse, mutect2, varscan2
- LGALS3BP | c.772C>T p.Q258* | Nonsense Mutation (SNP) | VAF 18/47 reads (38%) | catalogued as COSV53164773; called by muse, mutect2, varscan2
- LIPJ | c.584C>T p.S195L | Missense Mutation (SNP) | VAF 33/51 reads (65%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV64245257; called by muse, mutect2, varscan2
- LOXL2 | c.2133G>A p.Q711= | Splice Region (SNP) | VAF 12/34 reads (35%) | catalogued as COSV101207902; called by muse, mutect2, varscan2
- MAP3K21 | c.2632C>T p.P878S | Missense Mutation (SNP) | VAF 40/54 reads (74%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as rs765676884, COSV64041521; called by muse, mutect2, varscan2
- MAP7D2 | c.724A>G p.K242E | Missense Mutation (SNP) | VAF 47/59 reads (80%) | SIFT deleterious (0.04); PolyPhen benign (0.283); catalogued as COSV65526837; called by muse, mutect2, varscan2
- MAPK3 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as rs1393537562, COSV53772858; called by muse, mutect2, varscan2
- MASTL | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs185334476, COSV60910499; called by muse, mutect2, varscan2
- MCHR2 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56001959; called by muse, mutect2, varscan2
- MED15 | c.2200C>T p.P734S (on ENST00000263205 / NM_001003891.3; = p.P694S on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99487677; called by muse, mutect2, varscan2
- MED15 | c.2201C>T p.P734L (on ENST00000263205 / NM_001003891.3; = p.P694L on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs367828619; called by muse, mutect2, varscan2
- MEGF8 | c.3764C>T p.A1255V (on ENST00000251268 / NM_001271938.2; = p.A1188V on NM_001410.3) | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV52082077; called by muse, mutect2, varscan2
- MGA | c.5975A>C p.K1992T (on ENST00000219905 / NM_001164273.1; = p.K1783T on NM_001080541.2) | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.549); catalogued as COSV54952501; called by muse, mutect2, varscan2
- MGAM | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs782373494, COSV72074044, COSV72074183; called by muse, mutect2, varscan2
- MPP7 | c.1541A>G p.K514R | Missense Mutation (SNP) | VAF 51/133 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV61731608; called by muse, mutect2, varscan2
- MPP7 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.459); catalogued as rs868850825, COSV61730067; called by muse, mutect2, varscan2
- MPRIP | c.1291G>A p.G431R | Missense Mutation (SNP) | VAF 58/93 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100505712; called by muse, mutect2, varscan2
- MPRIP | c.1292G>A p.G431E | Missense Mutation (SNP) | VAF 58/94 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100505714; called by muse, mutect2, varscan2
- MROH7 | c.3418G>A p.E1140K | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as rs753679544, COSV59876024; called by muse, varscan2
- MUC17 | c.12922G>A p.V4308M | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.449); catalogued as COSV60286344; called by muse, mutect2, varscan2
- MYH4 | c.3859G>A p.E1287K | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV55116787; called by muse, mutect2, varscan2
- MYH4 | c.713C>T p.T238I | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99701281; called by muse, varscan2
- MYO15A | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.23); catalogued as rs202081139, COSV52755486; called by muse, mutect2, varscan2
- MYT1L | c.1480C>T p.P494S | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0.013); catalogued as rs778926184, COSV67718008; called by muse, mutect2, varscan2
- NCOA7 | c.226T>G p.L76V | Missense Mutation (SNP) | VAF 45/66 reads (68%) | SIFT deleterious (0.04); PolyPhen benign (0.116); catalogued as COSV57654660; called by muse, mutect2, varscan2
- NDUFA9 | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as COSV56928697; called by muse, mutect2, varscan2
- NEB | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.992); catalogued as COSV51133782; called by muse, mutect2, varscan2
- NEU4 | c.943G>A p.E315K (on ENST00000391969 / NM_001167602.3; = p.E327K on NM_080741.4) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs866120464, COSV57990147; called by muse, varscan2
- NEU4 | c.1028G>A p.G343D (on ENST00000391969 / NM_001167602.3; = p.G355D on NM_080741.4) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0.146); catalogued as COSV57990151; called by muse, varscan2
- NEXMIF | c.2803C>T p.P935S | Missense Mutation (SNP) | VAF 25/32 reads (78%) | SIFT tolerated (0.38); PolyPhen benign (0.079); catalogued as COSV50027849; called by muse, mutect2, varscan2
- NKX3-1 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs752426352, COSV66511969; called by muse, mutect2, varscan2
- NOD1 | c.1517C>T p.P506L | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs763425448, COSV56112132; called by muse, mutect2, varscan2
- NOL4 | c.1141G>A p.G381R | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV52345033; called by muse, mutect2, varscan2
- NOVA1 | c.560T>C p.I187T | Missense Mutation (SNP) | VAF 40/63 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV57475569; called by muse, mutect2, varscan2
- NR3C2 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV60989020; called by muse, mutect2
- OGDHL | c.884G>A p.G295E | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65101601; called by muse, mutect2, varscan2
- OR11H1 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV53271636; called by muse, mutect2, varscan2
- OR13F1 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as COSV58251411; called by muse, mutect2, varscan2
- OR14K1 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 49/69 reads (71%) | SIFT tolerated (0.05); PolyPhen benign (0.209); catalogued as rs1402761979, COSV51722635, COSV99315191; called by muse, mutect2, varscan2
- OR2G3 | c.695A>C p.E232A | Missense Mutation (SNP) | VAF 29/37 reads (78%) | SIFT tolerated (0.76); PolyPhen benign (0.012); catalogued as COSV60681437; called by muse, mutect2, varscan2
- OR2W1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs1226192074, COSV65851432, COSV65851562, COSV65852021; called by muse, mutect2, varscan2
- OR2Z1 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 78/112 reads (70%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.573); catalogued as rs782472476, COSV60691691; called by muse, mutect2, varscan2
- OR2Z1 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 78/113 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs143214344, COSV60692336; called by muse, mutect2, varscan2
- OR4C6 | c.380C>G p.P127R | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58603441, COSV58605175; called by muse, mutect2, varscan2
- OR5J2 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as COSV56620832; called by muse, mutect2, varscan2
- OR7G3 | c.934C>T p.H312Y | Missense Mutation (SNP) | VAF 45/49 reads (92%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs758913681, COSV59640291; called by muse, mutect2, varscan2
- OTUD4 | c.1150C>T p.P384S (on ENST00000447906 / NM_001366057.1; = p.P319S on NM_001102653.1) | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.194); catalogued as COSV71381787; called by muse, mutect2, varscan2
- PAK5 | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV62019935; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.840G>A p.M280I (on ENST00000374531 / NM_001037293.2; = p.M312I on NM_053016.6) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs1181980392, COSV57119104; called by muse, mutect2, varscan2
- PAPSS1 | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as rs148756122; called by muse, mutect2, varscan2
- PCDH18 | c.3277C>T p.P1093S | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as COSV61267820; called by muse, mutect2, varscan2
- PCDHAC2 | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1563379065, COSV99147627; called by muse, mutect2, varscan2
- PDGFC | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1056838662, COSV56847840; called by muse, mutect2, varscan2
- PDP1 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.16); catalogued as rs1194411687, COSV52601152; called by muse, mutect2, varscan2
- PDZRN3 | c.1787C>T p.S596F | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as rs760273615, COSV55197204; called by muse, mutect2, varscan2
- PGK2 | c.1117G>A p.G373S | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59163508; called by muse, mutect2, varscan2
- PHLDB3 | c.1826A>T p.Y609F | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT tolerated (0.06); PolyPhen benign (0.372); catalogued as COSV52669043; called by muse, mutect2, varscan2
- PIK3C2B | c.3457G>A p.D1153N | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65810673; called by muse, mutect2, varscan2
- PIKFYVE | c.1899G>A p.W633* | Nonsense Mutation (SNP) | VAF 16/37 reads (43%) | catalogued as COSV52240072; called by muse, mutect2, varscan2
- PKHD1 | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV61870894; called by mutect2, varscan2
- PLCB1 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV62047486; called by muse, mutect2, varscan2
- PLCB2 | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as rs760458157, COSV53032841; called by muse, mutect2, varscan2
- PLCH1 | c.1475G>A p.R492K (on ENST00000340059 / NM_001130960.2; = p.R504K on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.49); PolyPhen benign (0.145); catalogued as COSV100396041, COSV58212325; called by muse, varscan2
- PLEKHG2 | c.3110C>T p.P1037L | Missense Mutation (SNP) | VAF 71/88 reads (81%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as COSV52681694; called by muse, mutect2, varscan2
- PLXNA4 | c.4408G>A p.E1470K | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58119320; called by muse, mutect2, varscan2
- PLXNB1 | c.2776C>T p.P926S | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866132965, COSV56488853; called by muse, mutect2
- PPP1R9A | c.1160C>T p.S387L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1351417673, COSV56889961, COSV99194753, COSV99194970; called by muse, mutect2, varscan2
- PRAM1 | c.554C>T p.S185F | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as COSV55313296; called by muse, mutect2, varscan2
- PRB3 | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 74/216 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.469); catalogued as COSV54392878; called by muse, varscan2
- PSG1 | c.1007G>A p.R336K | Missense Mutation (SNP) | VAF 68/94 reads (72%) | SIFT tolerated (1); PolyPhen benign (0.297); catalogued as COSV54948105; called by muse, mutect2, varscan2
- PTPRD | c.2420G>A p.G807E | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61939913; called by muse, mutect2, varscan2
- PTPRR | c.524G>T p.G175V | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV51728365, COSV51730209; called by muse, mutect2, varscan2
- PTPRT | c.1487G>A p.G496E | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs554343349, COSV61975959, COSV62023515; called by muse, mutect2, varscan2
- PZP | c.2353G>A p.G785S | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs767516739, COSV54358695; called by muse, mutect2, varscan2
- RAB27B | c.269G>A p.R90K | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV50494665; called by muse, mutect2, varscan2
- RAB39A | c.242C>T p.S81F | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV57694761; called by muse, mutect2, varscan2
- RABGAP1 | c.1526C>T p.P509L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as COSV65392770; called by muse, mutect2, varscan2
- RERGL | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57461681; called by muse, mutect2, varscan2
- REV3L | c.3032T>C p.M1011T | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV62618109; called by muse, mutect2, varscan2
- RGS6 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as rs1469222528, COSV59573883; called by muse, mutect2, varscan2
- RIC3 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV58301736; called by muse, mutect2, varscan2
- RIMBP2 | c.2473G>A p.D825N | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as rs772506106, COSV55469192; called by muse, mutect2, varscan2
- RIPOR3 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 59/148 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs756686544, COSV50387679; called by muse, mutect2, varscan2
- RLBP1 | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.058); catalogued as COSV99175321; called by muse, mutect2, varscan2
- RLBP1 | c.10G>A p.G4R | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.125); catalogued as rs376705292; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ROBO2 | c.682C>T p.L228F | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV59907763; called by muse, mutect2, varscan2
- ROBO2 | c.2752G>A p.D918N | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.78); catalogued as COSV59907772; called by muse, mutect2, varscan2
- RP1L1 | c.5986G>A p.E1996K | Missense Mutation (SNP) | VAF 116/294 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV66754194; called by muse, mutect2, varscan2
- RXFP2 | c.1601G>A p.G534E | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs1474727748, COSV53633070; called by muse, mutect2, varscan2
- S1PR4 | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs779911002, COSV55740035; called by muse, mutect2, varscan2
- SALL1 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 39/58 reads (67%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as COSV51756264, COSV99173914; called by muse, mutect2, varscan2
- SALL3 | c.2642C>T p.S881L | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as rs772433157, COSV73305977; called by muse, mutect2, varscan2
- SAMD9L | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100561195, COSV59080760, COSV59080971; called by muse, mutect2, varscan2
- SARAF | c.535A>T p.I179F | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV56357242; called by muse, mutect2, varscan2
- SBF1 | c.2935G>A p.D979N | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as COSV62367241; called by muse, mutect2, varscan2
- SCAP | c.1733C>T p.S578F | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as COSV55560711; called by muse, mutect2, varscan2
- SCAPER | c.2023G>A p.E675K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV57738941; called by muse, mutect2
- SCN11A | c.2764G>A p.E922K | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.781); catalogued as rs1406051387, COSV56568993; called by muse, mutect2, varscan2
- SCN1A | c.2855G>A p.W952* (on ENST00000303395 / NM_001202435.3; = p.W941* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 51/151 reads (34%) | catalogued as CM032360, COSV100320046, COSV57667747; called by muse, mutect2, varscan2
- SCN4B | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867558470, COSV61252243; called by muse, mutect2, varscan2
- SDHAF2 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.535); catalogued as COSV57099049; called by muse, mutect2, varscan2
- SEMA5B | c.1942G>A p.G648S | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52095933; called by muse, mutect2, varscan2
- SEPTIN2 | c.85C>T p.R29* | Nonsense Mutation (SNP) | VAF 16/37 reads (43%) | catalogued as rs764085863, COSV100764909, COSV63472064; called by muse, mutect2, varscan2
- SERINC1 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as COSV60101916; called by muse, mutect2, varscan2
- SETD2 | c.7195C>T p.R2399* | Nonsense Mutation (SNP) | VAF 26/70 reads (37%) | catalogued as COSV57435779; called by muse, mutect2, varscan2
- SH3GL2 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV66047924; called by muse, mutect2, varscan2
- SHLD1 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.338); catalogued as rs773296265, COSV57436313; called by muse, mutect2, varscan2
- SLC17A6 | c.1226G>A p.R409K | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54134584, COSV54135594; called by muse, mutect2, varscan2
- SLC23A1 | c.1091G>A p.G364D | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs758487240, COSV62296337; called by muse, mutect2, varscan2
- SLC24A1 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV56051337; called by muse, mutect2, varscan2
- SLC26A4 | c.1652C>T p.S551F | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.588); catalogued as COSV55915916, COSV99706573; called by muse, mutect2, varscan2
- SLC29A3 | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated (0.19); PolyPhen benign (0.102); catalogued as COSV100928501; called by muse, mutect2, varscan2
- SLC9A2 | c.1997G>A p.R666Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); catalogued as rs572895281, COSV52131182; called by muse, mutect2, varscan2
- SLC9B2 | c.1392+1G>A p.X464_splice | Splice Site (SNP) | VAF 12/39 reads (31%) | catalogued as rs893138019, COSV60018780; called by muse, mutect2, varscan2
- SLCO1B1 | c.361T>C p.Y121H | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57010051; called by muse, mutect2, varscan2
- SLCO4C1 | c.925C>T p.R309* | Nonsense Mutation (SNP) | VAF 16/23 reads (70%) | catalogued as rs1408420153, COSV60512562; called by muse, mutect2, varscan2
- SMC6 | c.1394A>G p.Q465R | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as COSV61173663; called by muse, mutect2, varscan2
- SMG1 | c.6814C>T p.R2272C | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377702809; called by muse, mutect2
- SNAP25 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as COSV54771850, COSV54772802; called by muse, mutect2, varscan2
- SNX29 | c.2308C>T p.P770S | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV60057225; called by muse, mutect2, varscan2
- SNX9 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67583930; called by muse, mutect2, varscan2
- SP6 | c.1081G>T p.G361W | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV60617010, COSV60617273; called by muse, mutect2
- SPATA16 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100651815, COSV63528744; called by muse, mutect2, varscan2
- SPATS2L | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1477801302, COSV62347531; called by muse, mutect2, varscan2
- SPHKAP | c.1352T>A p.V451D | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60875891; called by muse, mutect2, varscan2
- SPINT1 | c.1213C>T p.P405S (on ENST00000344051 / NM_181642.3; = p.P389S on NM_003710.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.479); catalogued as COSV59801732; called by muse, mutect2, varscan2
- SPTA1 | c.3775G>A p.D1259N | Missense Mutation (SNP) | VAF 55/66 reads (83%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.506); catalogued as COSV63752023; called by muse, mutect2, varscan2
- SRRM3 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782801115, COSV58386795; called by muse, mutect2, varscan2
- STKLD1 | c.1081G>A p.G361S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV64312285; called by muse, mutect2, varscan2
- STOX2 | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.982); catalogued as COSV57851257; called by muse, mutect2, varscan2
- SUCLA2 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as COSV66222202; called by muse, varscan2
- SUCLA2 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV66222204; called by muse, varscan2
- SV2B | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57699453; called by muse, mutect2, varscan2
- SVEP1 | c.4039G>A p.D1347N | Missense Mutation (SNP) | VAF 80/240 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs1187886750, COSV57034334; called by muse, mutect2, varscan2
- SYCP2L | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51651040; called by muse, mutect2, varscan2
- SYNPO2 | c.1755G>A p.M585I | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV61109667; called by muse, mutect2, varscan2
- TBC1D9 | c.1328C>T p.A443V | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.017); catalogued as COSV71307306; called by muse, mutect2, varscan2
- TBX18 | c.1711C>T p.P571S | Missense Mutation (SNP) | VAF 25/30 reads (83%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.019); catalogued as rs752986259, COSV63736637; called by muse, mutect2, varscan2
- TDRD7 | c.2663C>T p.S888F | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as rs774468338; called by muse, mutect2
- TECRL | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as rs981827180, COSV67086737; called by muse, mutect2, varscan2
- TENT5C | c.316C>T p.Q106* | Nonsense Mutation (SNP) | VAF 25/40 reads (63%) | catalogued as COSV65616274; called by muse, mutect2, varscan2
- TET2 | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99482882; called by muse, mutect2, varscan2
- TET2 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs376009634, COSV54407618; called by muse, mutect2, varscan2
- TEX47 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.12); catalogued as COSV51878774; called by muse, mutect2, varscan2
- TFAM | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1375212511, COSV65876337; called by muse, mutect2, varscan2
- TFEC | c.493C>T p.L165F | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs779672171, COSV55399960; called by muse, mutect2, varscan2
- TGM5 | c.2123T>A p.I708N (on ENST00000220420 / NM_201631.4; = p.I626N on NM_004245.4) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55009793; called by muse, mutect2, varscan2
- THAP9 | c.1534C>T p.R512C | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs751938951, COSV56356065; called by muse, mutect2, varscan2
- THSD7B | c.2324G>A p.G775E | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55677942; called by muse, mutect2, varscan2
- TLR10 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.46); PolyPhen benign (0.051); catalogued as rs746499472, COSV58300021; called by muse, mutect2, varscan2
- TLR4 | c.1453G>A p.E485K (on ENST00000355622 / NM_138554.5; = p.E445K on NM_003266.4) | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1023995398, COSV62922298; called by muse, mutect2, varscan2
- TMPRSS11E | c.988C>T p.R330* | Nonsense Mutation (SNP) | VAF 37/50 reads (74%) | catalogued as rs1245131954, COSV59518027; called by muse, mutect2, varscan2
- TNNT3 | c.136G>A p.E46K (on ENST00000397301 / NM_001367846.1; = p.E35K on NM_006757.4) | Missense Mutation (SNP) | VAF 61/137 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.292); catalogued as COSV53486157; called by muse, mutect2, varscan2
- TNXB | c.12272T>C p.V4091A (on ENST00000647633; = p.V3844A on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.101); catalogued as COSV100926318; called by muse, mutect2, varscan2
- TNXB | c.5099C>T p.S1700F (on ENST00000647633; = p.S1453F on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs267600973, COSV64477827; called by muse, mutect2, varscan2
- TOP1MT | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV61316514; called by muse, mutect2, varscan2
- TPM2 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 82/123 reads (67%) | SIFT deleterious (0.05); PolyPhen benign (0.426); catalogued as COSV61405532; called by muse, mutect2, varscan2
- TRAF2 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs1042886761, COSV56037492; called by muse, mutect2, varscan2
- TRAF7 | c.173G>A p.R58K | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.97); catalogued as COSV58213957; called by muse, mutect2, varscan2
- TRPC3 | c.937G>A p.E313K (on ENST00000379645 / NM_001366479.2; = p.E240K on NM_003305.2) | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.491); catalogued as COSV53374590; called by muse, mutect2, varscan2
- TRPM6 | c.3593A>G p.K1198R | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.611); catalogued as COSV62508059; called by muse, mutect2, varscan2
- TRPV1 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.65); PolyPhen benign (0.079); catalogued as COSV51517599; called by muse, mutect2, varscan2
- TTC16 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64778196; called by muse, mutect2, varscan2
- TTN | c.89933G>A p.R29978Q (on ENST00000591111; = p.R22554Q on NM_003319.4) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | PolyPhen benign (0.182); catalogued as rs527976757, COSV60001614; ClinVar: uncertain significance; called by muse, mutect2
- TTN | c.74975T>G p.F24992C (on ENST00000591111; = p.F17568C on NM_003319.4) | Missense Mutation (SNP) | VAF 39/95 reads (41%) | PolyPhen possibly damaging (0.639); catalogued as COSV60001654; called by muse, mutect2, varscan2
- TTN | c.39872C>T p.S13291F (on ENST00000591111; = p.S5867F on NM_003319.4) | Missense Mutation (SNP) | VAF 27/62 reads (44%) | PolyPhen probably damaging (0.974); catalogued as COSV60001733; called by muse, mutect2, varscan2
- TTN | c.14131G>A p.V4711I (on ENST00000591111; = p.V3784I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/44 reads (45%) | PolyPhen benign (0); catalogued as COSV60001770; called by muse, mutect2, varscan2
- TUSC3 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV65880507; called by muse, mutect2, varscan2
- UBE3B | c.1009T>A p.L337M | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.117); catalogued as COSV55093078; called by muse, mutect2, varscan2
- UGCG | c.1037A>G p.K346R | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.858); catalogued as COSV65335811; called by muse, mutect2, varscan2
- UGT2B4 | c.1159G>A p.G387R | Missense Mutation (SNP) | VAF 62/145 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59316692; called by muse, mutect2, varscan2
- UGT2B7 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.197); catalogued as COSV59443000; called by muse, mutect2, varscan2
- UHRF1 | c.863C>T p.P288L (on ENST00000612630 / NM_001290050.1; = p.P301L on NM_013282.4) | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.08); PolyPhen benign (0.284); catalogued as COSV53574002; called by muse, mutect2, varscan2
- UNC79 | c.6685C>T p.Q2229* (on ENST00000393151 / NM_001346218.2; = p.Q2052* on NM_020818.5) | Nonsense Mutation (SNP) | VAF 13/17 reads (76%) | catalogued as COSV56383871; called by muse, mutect2, varscan2
- USP1 | c.891G>C p.Q297H | Missense Mutation (SNP) | VAF 28/41 reads (68%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.832); catalogued as COSV60573698; called by muse, mutect2, varscan2
- USP17L2 | c.1532G>A p.R511K | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.16); catalogued as COSV61555780; called by muse, mutect2, varscan2
- USP17L2 | c.1311G>A p.W437* | Nonsense Mutation (SNP) | VAF 30/120 reads (25%) | catalogued as COSV61555782; called by muse, mutect2, varscan2
- VIL1 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 22/71 reads (31%) | catalogued as COSV99945541; called by muse, mutect2, varscan2
- VPS13D | c.5110G>A p.E1704K | Missense Mutation (SNP) | VAF 57/73 reads (78%) | SIFT deleterious (0.04); PolyPhen benign (0.301); catalogued as rs1452798572, COSV50633851; called by muse, mutect2, varscan2
- VPS35L | c.1795G>A p.E599K | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV51981816, COSV99219190; called by muse, mutect2, varscan2
- VWF | c.4540T>C p.F1514L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54617780; called by muse, mutect2, varscan2
- WDFY3 | c.10571G>A p.R3524Q | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs199672909; called by muse, mutect2, varscan2
- WDR72 | c.1962G>A p.K654= | Splice Region (SNP) | VAF 11/43 reads (26%) | catalogued as COSV64745466; called by muse, mutect2, varscan2
- WDR74 | c.580G>A p.G194R | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV53679027; called by muse, mutect2, varscan2
- WSCD2 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.435); catalogued as COSV54581564; called by muse, mutect2, varscan2
- XIRP2 | c.832C>T p.P278S (on ENST00000628543; = p.P453S on NM_152381.6) | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV54695132; called by muse, mutect2, varscan2
- ZAN | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.68); PolyPhen benign (0.035); catalogued as rs369072360, COSV61805765; called by muse, mutect2, varscan2
- ZBTB6 | c.661C>T p.H221Y | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV65409789; called by muse, mutect2, varscan2
- ZFHX4 | c.4080G>A p.W1360* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as COSV50697330; called by muse, mutect2, varscan2
- ZNF135 | c.562C>T p.H188Y (on ENST00000313434 / NM_001289401.2; = p.H200Y on NM_003436.4) | Missense Mutation (SNP) | VAF 37/46 reads (80%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs772730588, COSV57881559; called by muse, mutect2, varscan2
- ZNF148 | c.463C>T p.L155F | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV62304145; called by muse, mutect2, varscan2
- ZNF292 | c.6410C>T p.A2137V | Missense Mutation (SNP) | VAF 30/33 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV60538581; called by muse, mutect2, varscan2
- ZNF341 | c.1255C>T p.P419S (on ENST00000375200 / NM_001282935.1; = p.P412S on NM_032819.4) | Missense Mutation (SNP) | VAF 80/186 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.197); catalogued as COSV100677858; called by muse, mutect2, varscan2
- ZNF341 | c.1256C>T p.P419L (on ENST00000375200 / NM_001282935.1; = p.P412L on NM_032819.4) | Missense Mutation (SNP) | VAF 80/187 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as COSV100677859; called by muse, mutect2, varscan2
- ZNF514 | c.439C>T p.L147F | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV54633739, COSV54633796; called by muse, mutect2, varscan2
- ZNF559 | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 37/41 reads (90%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV57835473; called by muse, mutect2, varscan2
- ZNF618 | c.2824G>A p.D942N (on ENST00000374126 / NM_001318042.2; = p.D849N on NM_133374.2) | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.395); catalogued as rs1213534642, COSV55920169; called by muse, mutect2, varscan2
- ZNF662 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.602); catalogued as rs760232360, COSV60241647; called by muse, mutect2, varscan2
- ZNF713 | c.872A>G p.H291R (on ENST00000633730 / NM_001366796.2; = p.H304R on NM_182633.3) | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1237158560, COSV70056646; called by muse, mutect2, varscan2
- ZNF777 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56097253; called by muse, mutect2, varscan2
- ADAMTS7 | c.1171_1178+16del p.X391_splice | Splice Site (DEL) | VAF 6/27 reads (22%) | called by mutect2, pindel, varscan2
- CDKN2A | c.262_266del p.E88Lfs*30 | Frame Shift Del (DEL) | VAF 7/14 reads (50%) | called by mutect2, varscan2
- CHST1 | c.358_384del p.S120_Y128del | In Frame Del (DEL) | VAF 16/103 reads (16%) | called by mutect2, pindel
- GDF10 | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- GPR161 | c.1114C>T p.P372S | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.32); called by muse, mutect2
- HNF1B | c.714G>A p.W238* | Nonsense Mutation (SNP) | VAF 43/62 reads (69%) | called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 56/343 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- IGLV3-12 | c.136A>T p.I46F | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- PCLO | c.11958del p.M3987* | Frame Shift Del (DEL) | VAF 92/257 reads (36%) | called by mutect2, varscan2
- TRGV2 | c.169C>T p.Q57* | Nonsense Mutation (SNP) | VAF 27/62 reads (44%) | called by muse, mutect2, varscan2
- ABCA12 | c.5061C>T p.S1687= (on ENST00000272895 / NM_173076.3; = p.S1369= on NM_015657.3) | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV55956412; called by muse, mutect2, varscan2
- ABCA2 | c.2592C>T p.I864= (on ENST00000614293; = p.I834= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as rs756913734, COSV99687634; called by muse, mutect2, varscan2
- ABCA6 | c.4498C>T p.L1500= | Silent (SNP) | VAF 63/176 reads (36%) | catalogued as COSV99446483; called by muse, mutect2, varscan2
- ABCA6 | c.4497C>T p.H1499= | Silent (SNP) | VAF 62/176 reads (35%) | catalogued as COSV99446487; called by muse, mutect2, varscan2
- ACACB | c.2202G>A p.V734= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV58132764; called by muse, mutect2, varscan2
- ACTR5 | c.690C>T p.Y230= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs1302337166, COSV54760356; called by muse, mutect2, varscan2
- ACVR2B | c.546C>T p.S182= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs886058386, COSV61702074; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAM7 | c.396C>T p.F132= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as COSV51538698; called by muse, varscan2
- ADAMTS16 | c.2118G>A p.E706= | Silent (SNP) | VAF 17/26 reads (65%) | catalogued as COSV56986181; called by muse, mutect2, varscan2
- ADGRB2 | c.2916C>T p.F972= | Silent (SNP) | VAF 33/38 reads (87%) | catalogued as COSV57072865; called by muse, mutect2, varscan2
- AFF3 | c.2202C>T p.I734= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as rs780306052, COSV57840505; called by muse, mutect2, varscan2
- ALMS1 | c.3393C>T p.D1131= | Silent (SNP) | VAF 54/147 reads (37%) | catalogued as COSV100042482; called by muse, mutect2, varscan2
- APBB1 | c.882C>T p.P294= | Silent (SNP) | VAF 31/72 reads (43%) | catalogued as rs1228184436, COSV54974862; called by muse, mutect2, varscan2
- ARHGAP33 | c.1918C>T p.L640= | Silent (SNP) | VAF 71/89 reads (80%) | catalogued as COSV50121999; called by muse, mutect2, varscan2
- ASF1B | c.63C>T p.P21= | Silent (SNP) | VAF 41/55 reads (75%) | catalogued as rs267605303, COSV54616012; called by muse, mutect2, varscan2
- BPIFB6 | c.462C>T p.P154= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV62754365; called by muse, mutect2, varscan2
- BTBD11 | c.1677G>A p.L559= (on ENST00000280758 / NM_001018072.2; = p.L96= on NM_001017523.2) | Silent (SNP) | VAF 48/99 reads (48%) | catalogued as COSV99775769; called by muse, mutect2, varscan2
- C8orf58 | c.285C>T p.S95= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as rs1563890814, COSV51515078; called by muse, mutect2, varscan2
- CACNG3 | c.936C>T p.T312= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV50066537; called by muse, mutect2, varscan2
- CAMTA1 | c.2031C>T p.F677= | Silent (SNP) | VAF 90/111 reads (81%) | catalogued as COSV57895971, COSV57913954; called by muse, mutect2, varscan2
- CASR | c.2997G>A p.V999= (on ENST00000490131; = p.V1076= on NM_000388.4) | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV56136751; called by muse, mutect2, varscan2
- CCDC136 | c.1074C>T p.S358= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV99922634; called by muse, mutect2, varscan2
- CCDC146 | c.2328C>T p.F776= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as COSV53547174; called by muse, mutect2, varscan2
- CD300LF | c.744C>T p.S248= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as COSV56896729; called by muse, mutect2, varscan2
- CD4 | c.345G>A p.K115= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV50590259; called by muse, mutect2, varscan2
- CD96 | c.903C>T p.I301= (on ENST00000283285 / NM_198196.3; = p.I285= on NM_005816.5) | Silent (SNP) | VAF 32/85 reads (38%) | catalogued as rs267599541, COSV51915405; called by muse, mutect2, varscan2
- CDCP1 | c.2362T>C p.L788= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as COSV56104878; called by muse, mutect2, varscan2
- CDH20 | c.1935C>T p.H645= | Silent (SNP) | VAF 48/119 reads (40%) | catalogued as COSV53008507; called by muse, mutect2, varscan2
- CDIN1 | c.813G>A p.T271= (on ENST00000437989; = p.T173= on NM_032499.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs372706927; called by muse, mutect2
- CHRNB2 | c.936C>T p.I312= | Silent (SNP) | VAF 44/55 reads (80%) | catalogued as rs281865071, CM055129, COSV63808042; called by muse, mutect2, varscan2
- CHST15 | c.735G>A p.G245= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as COSV60561581; called by muse, mutect2, varscan2
- CNTN5 | c.1755G>A p.V585= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs566928943, COSV54303996; called by muse, mutect2, varscan2
- COA1 | c.279C>T p.V93= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs765193246, COSV56241455; called by muse, mutect2, varscan2
- COL6A3 | c.798A>G p.V266= | Silent (SNP) | VAF 34/68 reads (50%) | catalogued as COSV55087070, COSV55109949; called by muse, mutect2, varscan2
- COLQ | c.9C>T p.V3= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as COSV67527176; called by muse, mutect2, varscan2
- CORO2A | c.1326C>T p.S442= | Silent (SNP) | VAF 46/128 reads (36%) | catalogued as COSV59662945; called by muse, mutect2, varscan2
- CPA3 | c.849G>A p.T283= | Silent (SNP) | VAF 27/44 reads (61%) | catalogued as rs200538548, COSV56047209; called by muse, mutect2, varscan2
- CPNE9 | c.255C>T p.F85= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV56004507; called by muse, mutect2, varscan2
- CSF2RB | c.2328C>T p.S776= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as rs1018805772, COSV53257197; called by muse, mutect2, varscan2
- CTAGE1 | c.1566G>A p.R522= | Silent (SNP) | VAF 44/97 reads (45%) | catalogued as COSV66942977, COSV66943331; called by muse, mutect2, varscan2
- CTNND1 | c.2830C>T p.L944= (on ENST00000399050 / NM_001085458.2; = p.L917= on NM_001331.3) | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as rs1226138979, COSV62383167, COSV62385348; called by muse, mutect2, varscan2
- CYP4X1 | c.1095G>A p.S365= | Silent (SNP) | VAF 33/40 reads (83%) | catalogued as rs368977020; called by muse, mutect2, varscan2
- CYYR1 | c.171C>T p.I57= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV54829539; called by muse, mutect2, varscan2
- DDX60L | c.3474G>A p.R1158= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as COSV52712193; called by muse, mutect2, varscan2
- DIS3L2 | c.2127C>T p.V709= | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as rs374731090; called by muse, mutect2, varscan2
- DNAH7 | c.2391A>G p.E797= | Silent (SNP) | VAF 47/137 reads (34%) | catalogued as COSV56760935; called by muse, mutect2, varscan2
- DST | c.9696G>A p.E3232= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs746870567, COSV99755972; called by muse, varscan2
- DYRK1B | c.1530C>T p.S510= | Silent (SNP) | VAF 21/29 reads (72%) | catalogued as COSV59913330; called by muse, mutect2, varscan2
- EPN3 | c.531C>T p.S177= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV52139342; called by muse, mutect2, varscan2
- ESX1 | c.1104C>T p.P368= | Silent (SNP) | VAF 12/18 reads (67%) | catalogued as rs782137936, COSV65424210; called by muse, varscan2
- EXTL3 | c.1290C>T p.F430= | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as rs199880183, COSV55037716; ClinVar: likely benign; called by muse, mutect2, varscan2
- EYA2 | c.330C>T p.S110= | Silent (SNP) | VAF 45/94 reads (48%) | catalogued as COSV57940812; called by muse, mutect2, varscan2
- FAM189B | c.1722C>T p.S574= | Silent (SNP) | VAF 18/24 reads (75%) | catalogued as COSV59169589; called by muse, mutect2, varscan2
- FAM83F | c.1245C>T p.S415= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV60999976; called by muse, mutect2, varscan2
- FAT4 | c.13356C>T p.T4452= | Silent (SNP) | VAF 38/77 reads (49%) | catalogued as COSV58680909; called by muse, mutect2, varscan2
- FBXW2 | c.1179G>A p.R393= | Silent (SNP) | VAF 26/78 reads (33%) | catalogued as COSV61596822; called by muse, mutect2, varscan2
- FKTN | c.384G>A p.R128= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV56309364, COSV56311302; called by muse, mutect2, varscan2
- FLG | c.5217G>A p.Q1739= | Silent (SNP) | VAF 243/287 reads (85%) | catalogued as rs1414704466, COSV64240628; called by muse, mutect2, varscan2
- FSCN3 | c.282C>T p.C94= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as rs773976456, COSV50000858; called by muse, mutect2, varscan2
- FURIN | c.1383C>T p.I461= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs202183883, COSV51576145; called by muse, mutect2, varscan2
- GABBR2 | c.1272G>A p.G424= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as COSV52300882; called by muse, mutect2, varscan2
- GCN1 | c.172C>T p.L58= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV56106751; called by muse, mutect2, varscan2
- GLDN | c.474G>A p.L158= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV59089775; called by muse, mutect2, varscan2
- GLI2 | c.3300G>A p.V1100= (on ENST00000361492 / NM_001374353.1; = p.V1117= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as rs1487916531, COSV58040022; called by muse, mutect2, varscan2
- GNLY | c.180G>A p.Q60= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV55703380; called by muse, mutect2, varscan2
- GPC2 | c.255C>T p.F85= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV99444714; called by muse, mutect2, varscan2
- GPLD1 | c.2052G>A p.V684= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV57756337; called by muse, mutect2, varscan2
- GPRASP1 | c.3423C>T p.S1141= | Silent (SNP) | VAF 39/49 reads (80%) | catalogued as rs145332528, COSV64355412; called by muse, mutect2, varscan2
- GRM3 | c.2616C>T p.L872= | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as rs745443013, COSV100862049, COSV64470591; called by muse, mutect2, varscan2
- GRM7 | c.1485C>T p.I495= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as rs150784421, COSV63140298; ClinVar: likely benign; called by muse, mutect2, varscan2
- GUCA1A | c.255G>A p.K85= | Silent (SNP) | VAF 59/139 reads (42%) | catalogued as COSV50003940; called by muse, mutect2, varscan2
- GUCY1A2 | c.1089C>T p.C363= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV56484512; called by mutect2, varscan2
- GYPB | c.231G>A p.T77= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs376038061, COSV51624857; called by muse, mutect2, varscan2
- H1-2 | c.288G>A p.T96= | Silent (SNP) | VAF 48/139 reads (35%) | catalogued as rs555588749, COSV100642234, COSV59190483; called by muse, mutect2, varscan2
- H2AC12 | c.378G>A p.K126= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as COSV63616896; called by muse, mutect2, varscan2
- H2BC6 | c.279G>A p.R93= | Silent (SNP) | VAF 36/113 reads (32%) | catalogued as rs745369773, COSV61591002; called by muse, mutect2, varscan2
- HEPACAM2 | c.1110C>T p.F370= (on ENST00000394468 / NM_001039372.4; = p.F358= on NM_198151.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV59059796; called by muse, mutect2, varscan2
- HHATL | c.1128C>T p.T376= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as COSV55134078; called by muse, mutect2, varscan2
- HK3 | c.288G>A p.L96= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV99458534; called by muse, mutect2, varscan2
- HOXA6 | c.60C>T p.S20= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV56072856; called by muse, mutect2, varscan2
- HOXD3 | c.1239C>T p.L413= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV50880005; called by muse, mutect2, varscan2
- IFT172 | c.1417C>T p.L473= | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as rs772607856, COSV53132678; called by muse, mutect2, varscan2
- IRS2 | c.3988T>C p.L1330= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV65478518; called by muse, mutect2, varscan2
- ITGA3 | c.1596C>T p.A532= | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as rs557710334, COSV50309077; called by muse, mutect2, varscan2
- KCNK13 | c.786C>T p.F262= | Silent (SNP) | VAF 29/37 reads (78%) | catalogued as rs370003272; called by muse, mutect2, varscan2
- KCNT1 | c.228C>T p.G76= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV53700023; called by muse, mutect2, varscan2
- KHDC1 | c.327C>T p.I109= (on ENST00000370384 / NM_001251874.2; = p.I36= on NM_030568.5) | Silent (SNP) | VAF 14/23 reads (61%) | catalogued as COSV57614602; called by muse, mutect2, varscan2
- KIDINS220 | c.5046C>T p.T1682= | Silent (SNP) | VAF 27/51 reads (53%) | catalogued as rs1270086786, COSV56752538; called by muse, mutect2, varscan2
- KIDINS220 | c.4185C>T p.S1395= | Silent (SNP) | VAF 55/122 reads (45%) | catalogued as rs1200581802, COSV56752542; called by muse, mutect2, varscan2
- KIF13A | c.4416T>C p.P1472= | Silent (SNP) | VAF 57/165 reads (35%) | catalogued as COSV52448315; called by muse, mutect2, varscan2
- KLHL38 | c.391T>C p.L131= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs372636699; called by muse, mutect2, varscan2
- KNSTRN | c.96G>A p.R32= | Silent (SNP) | VAF 38/85 reads (45%) | catalogued as COSV51103425; called by muse, mutect2, varscan2
- L3MBTL4 | c.18G>A p.R6= | Silent (SNP) | VAF 76/203 reads (37%) | catalogued as COSV53120058; called by muse, mutect2, varscan2
- LINGO4 | c.1011G>A p.Q337= | Silent (SNP) | VAF 72/85 reads (85%) | catalogued as COSV63214337; called by muse, mutect2, varscan2
- LIPC | c.954G>A p.K318= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as rs1287703150, COSV54421999; called by muse, mutect2, varscan2
- LRP6 | c.2259C>T p.L753= | Silent (SNP) | VAF 42/92 reads (46%) | catalogued as rs750823651, COSV53786378; called by muse, mutect2, varscan2
- LRRC15 | c.507C>T p.F169= | Silent (SNP) | VAF 90/200 reads (45%) | catalogued as rs149184445, COSV61649534; called by muse, mutect2, varscan2
- LRRIQ4 | c.825C>T p.L275= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV61619012; called by muse, mutect2, varscan2
- MAN1A1 | c.1399C>T p.L467= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as COSV63787318; called by muse, mutect2, varscan2
- MCF2L | c.1611C>T p.F537= (on ENST00000375608; = p.F505= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV100982549; called by muse, mutect2, varscan2
- MLKL | c.564C>T p.I188= | Silent (SNP) | VAF 80/118 reads (68%) | catalogued as COSV58204847; called by muse, mutect2, varscan2
- MPP3 | c.574C>T p.L192= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as COSV68197984; called by muse, mutect2, varscan2
- MRPS2 | c.477C>T p.A159= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs545937631, COSV54092853; called by muse, mutect2, varscan2
- MTUS2 | c.1050G>A p.G350= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as COSV70916394; called by muse, mutect2, varscan2
- MUC16 | c.1713C>T p.T571= | Silent (SNP) | VAF 48/57 reads (84%) | catalogued as COSV67461303; called by muse, mutect2, varscan2
- MUC17 | c.6387C>T p.S2129= | Silent (SNP) | VAF 86/236 reads (36%) | catalogued as COSV60286338; called by muse, mutect2, varscan2
- MYF6 | c.393G>A p.V131= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as COSV57351369; called by muse, mutect2, varscan2
- MYH3 | c.3687C>T p.I1229= | Silent (SNP) | VAF 32/42 reads (76%) | catalogued as rs778389007, COSV56863746; called by muse, mutect2, varscan2
- MYH4 | c.3882G>A p.Q1294= | Silent (SNP) | VAF 21/39 reads (54%) | catalogued as COSV55116777; called by muse, mutect2, varscan2
- MYH4 | c.714C>T p.T238= | Silent (SNP) | VAF 25/37 reads (68%) | catalogued as rs757676293, COSV99701280; called by muse, varscan2
- MYO1H | c.1926G>A p.R642= | Silent (SNP) | VAF 63/188 reads (34%) | catalogued as rs1463828593, COSV60443223; called by muse, mutect2, varscan2
- MYO3B | c.1221C>T p.S407= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV58701271; called by muse, mutect2, varscan2
- NBPF15 | c.432C>T p.L144= | Silent (SNP) | VAF 98/158 reads (62%) | catalogued as rs1168096985; called by muse, mutect2, varscan2
- NEB | c.2517C>T p.T839= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV51133333; called by muse, mutect2, varscan2
- NLRP14 | c.1503G>A p.G501= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV55064570; called by muse, mutect2, varscan2
- NLRP3 | c.2061G>A p.K687= | Silent (SNP) | VAF 35/45 reads (78%) | catalogued as COSV60223066; called by muse, mutect2, varscan2
- NMUR2 | c.567C>T p.F189= | Silent (SNP) | VAF 29/52 reads (56%) | catalogued as COSV54918728; called by muse, mutect2, varscan2
- NPR2 | c.765G>A p.L255= | Silent (SNP) | VAF 25/47 reads (53%) | catalogued as COSV61310308; called by muse, mutect2, varscan2
- NTNG2 | c.159G>A p.K53= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV62366200; called by muse, mutect2, varscan2
- NTPCR | c.114C>T p.T38= | Silent (SNP) | VAF 23/24 reads (96%) | catalogued as rs748694066, COSV64052417; called by muse, mutect2, varscan2
- NXPH1 | c.99G>A p.L33= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as COSV68313839; called by muse, mutect2, varscan2
- OGDH | c.2274C>T p.I758= | Silent (SNP) | VAF 37/87 reads (43%) | catalogued as rs761146861, COSV56048668; called by muse, mutect2, varscan2
- OGDHL | c.1623G>A p.E541= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV65101985; called by muse, mutect2, varscan2
- OPN4 | c.813C>T p.T271= | Silent (SNP) | VAF 17/25 reads (68%) | catalogued as rs1564620986, COSV54115781; called by muse, mutect2, varscan2
- OR10A3 | c.459C>T p.I153= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as COSV62459412; called by muse, mutect2, varscan2
- OR10A5 | c.138C>T p.I46= | Silent (SNP) | VAF 66/162 reads (41%) | catalogued as COSV55053896; called by muse, mutect2, varscan2
- OR10G2 | c.97C>T p.L33= | Silent (SNP) | VAF 23/35 reads (66%) | catalogued as COSV73390354; called by muse, mutect2, varscan2
- OR10H2 | c.723C>T p.T241= | Silent (SNP) | VAF 29/48 reads (60%) | catalogued as COSV59945848; called by muse, mutect2, varscan2
- OR1N1 | c.873G>A p.R291= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs756622437, COSV59195512; called by muse, mutect2, varscan2
- OR4F17 | c.93C>T p.I31= | Silent (SNP) | VAF 41/320 reads (13%) | catalogued as rs750396802, COSV100535539; called by muse, mutect2, varscan2
- OR51E2 | c.129C>T p.I43= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs574634498, COSV67807277; called by muse, mutect2, varscan2
- PADI6 | c.429G>A p.Q143= | Silent (SNP) | VAF 22/31 reads (71%) | catalogued as COSV61884327; called by muse, mutect2, varscan2
- PAK5 | c.387C>T p.S129= | Silent (SNP) | VAF 60/157 reads (38%) | catalogued as COSV62024198; called by muse, mutect2, varscan2
- PATJ | c.5088A>G p.G1696= | Silent (SNP) | VAF 31/40 reads (78%) | catalogued as COSV64502966; called by muse, mutect2, varscan2
- PCDHA4 | c.489G>A p.G163= | Silent (SNP) | VAF 21/32 reads (66%) | catalogued as rs1554124190, COSV63540628; called by muse, mutect2, varscan2
- PCDHA8 | c.144C>T p.I48= | Silent (SNP) | VAF 53/70 reads (76%) | catalogued as COSV65335045; called by muse, mutect2, varscan2
- PCDHAC2 | c.1728C>A p.A576= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV99147614; called by muse, mutect2, varscan2
- PCNP | c.183C>T p.L61= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as COSV54575833; called by muse, mutect2, varscan2
- PKD1 | c.6243C>T p.A2081= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as rs370526001; called by muse, mutect2, varscan2
- PLCH1 | c.1476G>A p.R492= (on ENST00000340059 / NM_001130960.2; = p.R504= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as COSV58195783; called by muse, varscan2
- PLXNB2 | c.3102C>T p.S1034= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as rs1408945552, COSV63781162; called by muse, mutect2
- PNPLA6 | c.2076C>T p.G692= (on ENST00000414982 / NM_001166111.2; = p.G644= on NM_006702.5) | Silent (SNP) | VAF 42/46 reads (91%) | catalogued as COSV55377068; called by muse, mutect2, varscan2
- PRKCZ | c.768A>G p.R256= | Silent (SNP) | VAF 36/42 reads (86%) | catalogued as COSV66066953; called by muse, mutect2, varscan2
- PRPF18 | c.426C>T p.I142= | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as rs745528761, COSV60725063; called by muse, mutect2, varscan2
- PRSS12 | c.936C>T p.A312= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as rs12505679, COSV99628972; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- PRSS16 | c.1191C>T p.L397= | Silent (SNP) | VAF 38/100 reads (38%) | catalogued as COSV57915331; called by muse, mutect2, varscan2
- RAB22A | c.546C>T p.L182= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV54831180; called by muse, mutect2, varscan2
- RYR3 | c.9807C>T p.I3269= (on ENST00000389232; = p.I3270= on NM_001036.6) | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV66785621; called by muse, mutect2, varscan2
- SAMD9L | c.4716C>T p.S1572= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV59080967; called by muse, mutect2, varscan2
- SCN11A | c.1020G>A p.T340= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs267599814, COSV56565234; called by muse, mutect2, varscan2
- SCN2A | c.3573G>A p.G1191= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs267598962, COSV51838673; called by muse, mutect2, varscan2
- SEC24B | c.2829C>T p.V943= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as COSV54497861; called by muse, mutect2, varscan2
- SET | c.472C>T p.L158= (on ENST00000372692 / NM_001374326.1; = p.L145= on NM_003011.4) | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV59002255; called by muse, mutect2, varscan2
- SIGLEC1 | c.2250G>C p.L750= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV52462228; called by muse, mutect2, varscan2
- SIGLEC6 | c.1083C>T p.F361= | Silent (SNP) | VAF 29/37 reads (78%) | catalogued as rs758817540, COSV58433500; called by muse, mutect2, varscan2
- SKOR1 | c.531G>A p.E177= | Silent (SNP) | VAF 35/80 reads (44%) | catalogued as COSV58245389; called by muse, mutect2, varscan2
- SLC29A3 | c.834G>A p.Q278= | Silent (SNP) | VAF 19/32 reads (59%) | catalogued as COSV100928500; called by muse, mutect2, varscan2
- SLC38A10 | c.456C>T p.S152= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as COSV55844797; called by muse, varscan2
- SLC38A3 | c.930C>T p.L310= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs140222807, COSV68843967; called by muse, mutect2, varscan2
- SLC51B | c.127C>T p.L43= | Silent (SNP) | VAF 39/106 reads (37%) | catalogued as COSV54981853; called by muse, mutect2, varscan2
- SLC5A8 | c.228C>T p.S76= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV73310551; called by muse, mutect2, varscan2
- SLITRK1 | c.666C>T p.S222= | Silent (SNP) | VAF 32/62 reads (52%) | catalogued as COSV65675190; called by muse, mutect2, varscan2
- SOAT2 | c.480C>T p.F160= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs200442641, COSV56859217; called by muse, mutect2, varscan2
- SPATA31E1 | c.3624G>A p.R1208= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs769016236, COSV57790967; called by muse, mutect2, varscan2
- SPTAN1 | c.5037C>T p.A1679= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as rs776927572, COSV100823804, COSV63986650; called by muse, mutect2, varscan2
- SSB | c.96G>A p.R32= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV53628982; called by muse, mutect2, varscan2
- SYNJ1 | c.894A>G p.Q298= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs1050709204, COSV59147305; called by muse, mutect2, varscan2
- TARBP1 | c.4413C>T p.I1471= | Silent (SNP) | VAF 44/59 reads (75%) | catalogued as rs752798421, COSV50182502; called by muse, mutect2, varscan2
- TAS2R60 | c.672G>A p.R224= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as COSV60330620; called by muse, mutect2, varscan2
- TBC1D1 | c.432C>T p.I144= | Silent (SNP) | VAF 39/84 reads (46%) | catalogued as rs1350789757, COSV54717770; called by muse, mutect2, varscan2
- TEKT4 | c.1134A>T p.A378= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV54624358; called by muse, mutect2
- TET2 | c.40C>T p.L14= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV99482881; called by muse, mutect2, varscan2
- TFCP2L1 | c.1287C>T p.I429= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV55290641; called by muse, mutect2, varscan2
- THSD7B | c.534G>A p.R178= | Silent (SNP) | VAF 60/186 reads (32%) | catalogued as COSV55678825; called by muse, mutect2, varscan2
- TIPARP | c.1557T>C p.F519= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV55813826; called by muse, mutect2, varscan2
- TMC2 | c.1809C>T p.F603= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs1276153647, COSV62651944; called by muse, mutect2, varscan2
- TMC6 | c.1188C>T p.A396= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs745973954, COSV59808685; called by muse, mutect2, varscan2
- TMEM186 | c.606C>T p.F202= | Silent (SNP) | VAF 39/118 reads (33%) | catalogued as COSV51631499; called by muse, mutect2, varscan2
- TMEM82 | c.681C>T p.F227= | Silent (SNP) | VAF 10/12 reads (83%) | catalogued as rs1459447875, COSV53816756; called by muse, mutect2, varscan2
- TNNC1 | c.336C>T p.I112= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as rs763584637, COSV51767222; ClinVar: likely benign; called by muse, mutect2, varscan2
- TRANK1 | c.5079C>T p.F1693= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs759542279, COSV57147721; called by muse, mutect2, varscan2
- TRIM71 | c.2172C>T p.I724= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV67470479, COSV67470714; called by muse, mutect2, varscan2
- TTLL11 | c.1527C>T p.P509= | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as COSV58645475; called by muse, mutect2, varscan2
- TTN | c.56373T>C p.F18791= (on ENST00000591111; = p.F11367= on NM_003319.4) | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as COSV60001695; called by muse, mutect2
- VARS1 | c.2577C>T p.H859= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs764173220, COSV63304504; called by muse, varscan2
- VENTX | c.603C>T p.S201= | Silent (SNP) | VAF 15/21 reads (71%) | catalogued as rs376205046, COSV58084431; called by muse, mutect2, varscan2
- VGLL4 | c.855C>T p.S285= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV56076494; called by muse, mutect2, varscan2
- VIL1 | c.297C>T p.V99= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV99945540; called by muse, mutect2, varscan2
- VXN | c.600C>T p.T200= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV59685719; called by muse, mutect2, varscan2
- WWC1 | c.3294C>T p.F1098= | Silent (SNP) | VAF 14/20 reads (70%) | catalogued as rs767462423, COSV54649792; called by muse, mutect2, varscan2
- ZDHHC23 | c.415C>T p.L139= | Silent (SNP) | VAF 41/95 reads (43%) | catalogued as rs1424138684, COSV57629358; called by muse, mutect2, varscan2
- ZG16B | c.375C>T p.A125= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as COSV66525807; called by muse, mutect2, varscan2
- ZNF239 | c.555G>A p.G185= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV60018521; called by muse, mutect2, varscan2
- ZNF704 | c.1107C>T p.P369= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV59922272; called by muse, mutect2, varscan2
- ZNF76 | c.348G>A p.E116= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs1379950038, COSV57591335; called by muse, mutect2, varscan2
- ZNF775 | c.843C>T p.F281= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV61613469; called by muse, mutect2, varscan2
- ZNF831 | c.2997T>G p.G999= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV64039340; called by muse, mutect2, varscan2
- AC073310.1 | n.127C>T | RNA (SNP) | VAF 9/31 reads (29%) | catalogued as rs529814469; called by muse, mutect2, varscan2
- AL133467.5 | chr14:95663554 C>T | 3'Flank (SNP) | VAF 10/15 reads (67%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65506226 C>T | 3'Flank (SNP) | VAF 14/19 reads (74%) | catalogued as rs758298504; called by muse, mutect2, varscan2
- APOL3 | c.224-3447G>A | Intron (SNP) | VAF 20/61 reads (33%) | catalogued as COSV100652076; called by muse, mutect2, varscan2
- ARHGAP15 | c.-1T>A | 5'UTR (SNP) | VAF 5/15 reads (33%) | catalogued as COSV99710690; called by mutect2, varscan2
- CDC14B | c.160+633G>A | Intron (SNP) | VAF 54/129 reads (42%) | called by muse, mutect2, varscan2
- GGTLC2 | c.361-24C>T | Intron (SNP) | VAF 39/104 reads (38%) | catalogued as COSV67854027; called by muse, mutect2, varscan2
- KIF16B | c.3498+2983C>T | Intron (SNP) | VAF 8/19 reads (42%) | catalogued as rs765853333, COSV100734289; called by muse, mutect2, varscan2
- LCN8 | c.93+536C>T | Intron (SNP) | VAF 13/28 reads (46%) | catalogued as rs199795045; called by muse, varscan2
- LCN8 | c.93+535C>T | Intron (SNP) | VAF 13/28 reads (46%) | catalogued as COSV100293413; called by muse, varscan2
- LINC01098 | n.463A>C | RNA (SNP) | VAF 26/70 reads (37%) | catalogued as rs749803334; called by muse, mutect2, varscan2
- OR2U1P | n.3G>A | RNA (SNP) | VAF 16/36 reads (44%) | called by muse, mutect2
- PRB3 | c.604+27G>A | Intron (SNP) | VAF 112/493 reads (23%) | catalogued as rs768543627, COSV99685761; called by muse, varscan2
- SAA2 | c.*1G>A | 3'UTR (SNP) | VAF 13/34 reads (38%) | catalogued as COSV99879329; called by muse, mutect2, varscan2
- SNORD115-21 | n.18C>T | RNA (SNP) | VAF 80/229 reads (35%) | called by muse, mutect2, varscan2
- SNORD115-5 | n.16A>C | RNA (SNP) | VAF 83/243 reads (34%) | called by muse, mutect2, varscan2
- TTN | c.10360+5386C>T | Intron (SNP) | VAF 14/41 reads (34%) | catalogued as COSV100612743; called by muse, mutect2, varscan2
- VPS26C | c.*2C>T | 3'UTR (SNP) | VAF 7/23 reads (30%) | catalogued as COSV99898530; called by muse, varscan2
- WDR64 | c.*2G>A | 3'UTR (SNP) | VAF 30/33 reads (91%) | catalogued as rs1235126648, COSV100843778; called by muse, mutect2, varscan2
